Surgical pathology report (de-identified scan), TCGA case TCGA-R5-A7O7, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R5-A7O7-01A (Primary Tumor).

[page 1 of 2]
CSCF ICD-O-3
Adenocarcinoma, tubular 8211/3

Specimen Date/Time:

Path
Adenocarcinoma NOS 8140/3

DIAGNOSIS

(A) ESOPHAGUS, 34 CM, BIOPSY:

Small focus of atypical glands with crush artifact, at least high-grade dysplasia.
Squamous mucosa with chronic inflammation.

(B) ESOPHAGUS, TUMOR, BIOPSY:

ADENOCARCINOMA, MODERATELY DIFFERENTIATED ASSOCIATED WITH SQUAMOUS MUCOSA.

CSCF
Site Gastroesophageal junction C16.0
Path
Lower third of esophagus C15.5
9/25/13

GROSS DESCRIPTION

- (A) BIOPSY AT 34 CM – Four pale gray soft tissue fragments, 0.5 x 0.4 x 0.3 cm in aggregate. Entirely submitted in A.
(B) TUMOR – Multiple pink-gray soft tissue fragments, 0.8 x 0.4 x 0.4 cm in aggregate. Entirely submitted in B.

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Per TSS, Dx Discrepancy form
states TCGA tumor to be
Intestinal Adenocarcinoma, tubular type.

ICD-O Discrepancy	☐	☒
Pr. Malignancy History	☐	☒
Dual, Synchronous Primary Noted	☐	☒

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Stomach adenocarcinoma adenocarcinoma)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report Moderately diff adenocarcinoma

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF Intestinal Adenocarcinoma Tubular Type

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

The pathologists at always use the gastric cancer classification as intestinal and diffuse (which is so as per TCGA).

do not

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 29c8f056-dfee-4d92-b27b-0d9b14c731bf (TCGA-R5-A7O7.5FF1DAAF-B0E7-4D72-B255-4E0136EA4B75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).